Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A45Y, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A45Y-01A (Primary Tumor).

[page 1 of 2]
DOB:

Sex: M

Physician:

Accession:

Received:

Pathologist:

Case type: Surgical History

**** Case Imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to the section "SPECIMEN" may have been added. ****

SUPPLEMENTAL REPORT
DIAGNOSIS:

(B) TOTAL LARYNGECTOMY:
SQUAMOUS CARCINOMA IN THYROID CARTILAGE.

1CD-0-3

Carcinoma, squamous cell, NOS 8070/3

Site: larynx, NOS C32.9

W
10/1/12

Entire report and diagnosis completed by:
Report released by:

DIAGNOSIS

(A) LARYNX BIOPSY:

INVASIVE POORLY DIFFERENTIATED SQUAMOUS CARCINOMA.

(B) TOTAL LARYNGECTOMY AND BILATERAL NECK DISSECTION:

INVASIVE POORLY DIFFERENTIATED SQUAMOUS CARCINOMA, PRESENCE OF
LYMPHATIC AND PERINEURAL INVASION INVOLVING RIGHT AND LEFT
FALSE VOCAL CORD, RIGHT AND LEFT TRUE VOCAL CORDS, VENTRICLES,
PRESENCE OF SUBGLOTTIC EXTENSION ON THE LEFT SIDE MEASURING
7.0 MM.

TUMOR INVADING PERICHONDRIUM.

Margins of excision free of tumor.

Ten right lymph nodes, no tumor.

Two left lymph nodes, no tumor.

(C) LEFT LYMPH NODES:

Three lymph nodes, no tumor.

(D) RIGHT EPIGLOTTIC FOLD MARGIN:

Squamous mucosa, no tumor.

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

(A) LARYNX - Three portions of tan-pink-purple soft tissue ranging from 0.4 to
0.2 cm in greatest dimension. Submitted for frozen section examination as A.

FFS/DX: INVASIVE SQUAMOUS CELL CARCINOMA.

[page 2 of 2]
DOB:

Sex: M

Physician:

Received:

Pathologist:

Accession:

Case type: Surgical History

(B) TOTAL LARYNGECTOMY AND BILATERAL NECK DISSECTION - A total laryngectomy and attached fibroadipose tissue with overall measurements of 9.0 x 6.0 x 5.5 cm. An ulcerated friable mass involving the right transglottic and the midline and glottic and subglottic lesion on the left measuring 4.5 x 3.0 x 1.0 cm. The mucosal margin appears grossly uninvolved. Small fragments of soft tissue (1.5 x 1.5 cm) on the right and on the left were identified, and the lymph node was submitted separately on the right and left neck dissection. The specimen is submitted entirely from right to left in cassettes B2-B14 for the laryngeal cancer; B15-B17, right lymph node; B18, section of thyroid; B19-B21, lymph nodes from the left side.

(C) LEFT LYMPH NODES - Received are three pink-tan lymph nodes ranging from 0.9 x 0.8 x 0.6 to 1.9 x 1 x 0.7 cm. Entirely submitted in C1 through C3, one lymph node each.

(D) RIGHT EPIGLOTTIS FOLD MARGIN - A single portion of tan-pink soft tissue (1.2 x 0.2 x 0.2 cm). Submitted in toto for frozen section examination as D.

*FS/DX: MUCOSA, NO TUMOR PRESENT.

SNOMED CODES

M-80703 T-24100

Page 2 of 2

History Case Pathology Report
File under: Pathology

History Case Pathology

Source: NCI Genomic Data Commons file 7be985f9-24fd-4175-a86e-7174b566e3e9 (TCGA-CV-A45Y.622179CF-B6E7-4854-B9D6-9D0AE5028AE4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).